Somatic mutation profile of tumor specimen 0DSF03 from CCDI case PBCHVI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain stem; Age at diagnosis: 6.4 years (2,348 days).
Specimen 0DSF03: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12cb2935-4a9b-4623-b5cd-29d09c8c510c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSEYX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47561ae4-1a33-49ed-84f8-c0ff0ff025f8

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AUTS2 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 21/736 reads (3%) | catalogued as rs1562957809, COSV61394590; ClinVar: pathogenic; called by muse, mutect2
- HSPA12A | c.1595G>A p.R532Q | Missense Mutation (SNP) | VAF 108/701 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs782629136, COSV65021172; called by muse, mutect2, varscan2
- AFP | c.322T>G p.Y108D | Missense Mutation (SNP) | VAF 28/892 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2
- PDS5A | c.1221A>T p.T407= | Silent (SNP) | VAF 18/485 reads (4%) | catalogued as rs1314475606; called by muse, mutect2
